Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A68F, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A68F-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 1
SEX: F

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Pheochromocytoma of the left adrenal gland.

PROCEDURE: SPGD

VERIFIED BY:

1. "Periaortic mass" Received in formalin in a small container is a 2.9 x 2.1 x 1.2 cm portion of tan soft tissue. Cut surfaces reveal a well-circumscribed, tan, homogeneous mass with solid cut surfaces. no areas of cystic degeneration or necrosis present. Representative sections submitted in two cassettes. (each)
2. "Left adrenal gland" Received in formalin in a medium container is a 36.91 gram, 9.7 x 4.7 x 2.4 cm adrenal gland. Cut sectioning reveals a well-circumscribed 3.3 x 2.5 x 4.5 cm solid mass. Cut surface is tan and homogeneous. There are no areas of necrosis present. There is a rim of uninvolved adrenal gland surrounding the mass which appears to arise from the medulla. The margins are grossly negative.
- 2A-D. Representative sections of mass. (each).
- 2E. representative section of mass and adjacent adrenal gland.

PROCEDURE: SPDX

VERIFIED BY

1. Periaortic soft tissue, excision: Paraganglioma (2.9 cm).
2. Left adrenal gland, resection: Pheochromocytoma (4.5 cm), margins negative.

I, _____, the signing staff pathologist, have
personally examined and interpreted the slides from this case.

	Yes	No
Staging Discrepancy		
or Malignancy History		
viewer Initials	Date Reviewed: 6/11/13	

Source: NCI Genomic Data Commons file e5da769f-cd21-465a-9bae-396c28f6977b (TCGA-RW-A68F.37D2306F-2311-4A67-9486-8193B18808AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).